CCDI case PBBRRI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/4f0a3427-2cb1-4d08-a4b1-a3054ea7e5b0

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 14.1 years (5,133 days).

Biospecimens (3 samples)
- Sample 0DFA8Z: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFA99: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DFA9D: Tissue type: Tumor; Specimen type: Solid Tissue.
